Gene-level copy-number profile of tumor specimen TCGA-FF-8042-01A from TCGA case TCGA-FF-8042, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 57.5 years (21,005 days).
Specimen TCGA-FF-8042-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.176c6c1e-0489-4c91-9678-a0b76d05f440.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FF-8042-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1c1dcef-3bb6-4f58-bca0-24bd3c691fda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 3,753; copy number 2: 40,811; copy number 3: 12,412; copy number 4: 1,797; copy number 5: 445; copy number 6: 180; copy number 7: 353; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FF-8042-01A-11D-2209-01): tumor purity 0.82, ploidy 2.34, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,926,094–19,967,994, 3 genes: AL591222.1, AL591222.2, AL591222.3.
- chr9:21,802,636–22,455,740, 16 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:23,690,104–23,956,444, 5 genes: ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3.
- chr22:22,762,294–22,873,440, 18 genes: IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 983 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,698,259–188,154,057, 11 genes, copy number 5–12: RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr8:115,408,496–122,428,551, 67 genes, copy number 5 (broad region; genes not listed).
- chr8:122,485,515–122,489,815, 1 gene, copy number 5: AC108136.1.
- chr18:47,390–5,630,700, 117 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:20,946,906–41,819,421, 289 genes, copy number 5–7 (broad region; genes not listed).
- chr18:42,649,520–53,535,903, 165 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:54,151,606–57,803,315, 60 genes, copy number 7 (within-gene range 4–7): MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459, TCF4, TCF4-AS1, MIR4529, TCF4-AS2, AC022031.2, RPL21P126, LINC01415, AC022031.1, AC027584.1, LINC01416, AC009271.1, AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1, WDR7, Y_RNA, AC012301.1, U3, WDR7-OT1, AC012301.2, LINC-ROR, AC100775.1, BOD1L2, LINC02565, RNU6-737P, ST8SIA3, AC090340.1, ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1, RNU6-742P.
- chr18:59,696,459–63,367,228, 57 genes, copy number 7: AC010776.2, AC010776.3, RPS26P54, GLUD1P4, AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1, AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR.
- chr18:65,423,958–80,247,514, 215 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
